Somatic mutation profile of tumor specimen TCGA-67-6215-01A (aliquot TCGA-67-6215-01A-11D-1753-08) from TCGA case TCGA-67-6215, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.9 years (19,310 days).
Specimen TCGA-67-6215-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d08add4-14c6-4cce-9232-07d7a1c7b290.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-6215-10A (Blood Derived Normal), aliquot TCGA-67-6215-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d968a88-d8e1-44bb-a72b-caf60dccd001

The open-access MAF lists 110 somatic variants for this specimen: 88 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 18, RNA 4, Splice Site 2, Nonsense Mutation 2, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.9023G>A p.R3008H | Missense Mutation (SNP) | VAF 24/105 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587781894, CM092589, COSV53726175, COSV53741856; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2
- ABCC6 | c.3385G>T p.E1129* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV52741998; called by muse, mutect2, varscan2
- ACAD11 | c.385T>G p.F129V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53894332; called by muse, mutect2, varscan2
- ALDH1A2 | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 106/315 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759343623, COSV51078725; called by muse, mutect2, varscan2
- ALDH1L2 | c.2678T>G p.F893C | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374849803, COSV51553958; called by muse, mutect2, varscan2
- ANKRD55 | c.709A>C p.I237L | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.322); catalogued as COSV61944848; called by muse, mutect2, varscan2
- ANTXR1 | c.779A>C p.K260T | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.832); catalogued as COSV58010421; called by muse, mutect2, varscan2
- APOB | c.6402A>C p.Q2134H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV51927140; called by muse, mutect2, varscan2
- ATP1A4 | c.299T>G p.F100C | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63625774; called by muse, mutect2, varscan2
- ATP6V1B2 | c.178T>G p.L60V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.181); catalogued as COSV52352961; called by muse, mutect2, varscan2
- C1orf112 | c.1972A>G p.K658E | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as COSV53677236; called by muse, mutect2
- C2CD5 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as COSV61723347; called by muse, mutect2, varscan2
- CACNA1B | c.874T>G p.F292V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.438); catalogued as COSV53117480, COSV99495722; called by muse, mutect2, varscan2
- CCDC88B | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57265255; called by muse, mutect2, varscan2
- CERKL | c.1529A>C p.E510A (on ENST00000339098 / NM_001030311.2; = p.E484A on NM_201548.5) | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.184); catalogued as COSV59204748; called by muse, mutect2, varscan2
- CFAP43 | c.2065A>C p.M689L | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV53376827; called by muse, mutect2
- CR2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs752969830, COSV65506391; called by muse, mutect2, varscan2
- CYLD | c.341A>C p.K114T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV61093413; called by muse, mutect2
- CYP4F8 | c.1273T>G p.F425V | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV57853406; called by muse, mutect2, varscan2
- CYP4Z1 | c.365-2A>C p.X122_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV61964055; called by muse, mutect2, varscan2
- DEFB125 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV66703129, COSV66703142; called by muse, mutect2, varscan2
- DSG4 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as rs1443350058, COSV57389141; called by muse, mutect2, varscan2
- EFHB | c.2435A>C p.E812A | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55545621; called by muse, mutect2, varscan2
- EPG5 | c.5447A>C p.K1816T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as COSV56346080; called by muse, mutect2, varscan2
- EPG5 | c.540A>C p.E180D | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV56346095; called by muse, mutect2
- ERAP2 | c.2753T>G p.F918C | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV65938973; called by muse, mutect2, varscan2
- FAM214A | c.3110T>A p.L1037H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55922695; called by muse, mutect2, varscan2
- FUT7 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55798640; called by muse, mutect2, varscan2
- GALNT12 | c.826A>C p.I276L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.321); catalogued as COSV66662283; called by muse, mutect2, varscan2
- GAS7 | c.1019G>A p.R340Q (on ENST00000432992 / NM_201433.2; = p.R200Q on NM_003644.3) | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs1325240094, COSV60432781, COSV60437600; called by muse, mutect2, varscan2
- HEATR1 | c.3328A>G p.I1110V | Missense Mutation (SNP) | VAF 94/158 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs1246982024, COSV63979999; called by muse, mutect2, varscan2
- HPS3 | c.2384T>G p.L795R | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV56053192; called by muse, mutect2, varscan2
- HRNR | c.6277A>G p.S2093G | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV64255278; called by muse, varscan2
- HS6ST1 | c.1075T>C p.Y359H | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99389362; called by muse, varscan2
- HSP90B1 | c.1650A>T p.E550D | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV55354401, COSV55355070; called by muse, mutect2, varscan2
- KIFAP3 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV63031705; called by muse, mutect2, varscan2
- KMT2E | c.3753A>G p.Q1251= | Splice Region (SNP) | VAF 9/22 reads (41%) | catalogued as rs776219881, COSV57570632; called by muse, mutect2, varscan2
- KRR1 | c.714T>A p.S238R | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99875504; called by muse, mutect2
- LCT | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV51545386; called by muse, varscan2
- LRCH1 | c.346T>A p.L116M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV60844801; called by muse, mutect2, varscan2
- LRRC37A2 | c.4081T>C p.S1361P | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1428718343, COSV60235932; called by muse, mutect2
- MICAL3 | c.205T>G p.L69V | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52893582; called by muse, mutect2, varscan2
- MTMR7 | c.734T>G p.L245R | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51663884; called by muse, mutect2, varscan2
- MYO1C | c.3166-1G>A p.X1056_splice (on ENST00000648651 / NM_001080779.2; = p.X1021_splice on NM_033375.5) | Splice Site (SNP) | VAF 32/81 reads (40%) | catalogued as COSV100704237; called by muse, mutect2, varscan2
- NCAN | c.1673G>A p.G558D | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV53047886; called by muse, mutect2
- NCSTN | c.310A>G p.T104A | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV54185994; called by muse, mutect2, varscan2
- NMUR2 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV54917764; called by muse, mutect2, varscan2
- OR4A5 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.023); catalogued as COSV60521851; called by muse, mutect2, varscan2
- PABPC3 | c.655A>G p.S219G | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99879019; called by muse, mutect2
- PARP3 | c.542A>T p.Q181L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV51753348; called by muse, mutect2
- PGBD1 | c.747G>C p.E249D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.077); catalogued as COSV52551781; called by muse, mutect2, varscan2
- PLXND1 | c.1715A>G p.E572G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs765746868, COSV60710294; called by muse, varscan2
- PNPLA8 | c.1409A>C p.K470T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57551717; called by muse, mutect2, varscan2
- POLK | c.1696A>G p.S566G | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54033015; called by muse, mutect2
- PRF1 | c.283T>C p.W95R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM012645, COSV64614519; called by muse, mutect2, varscan2
- PSG2 | c.765T>G p.D255E | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1058095, COSV61544754; called by muse, varscan2
- RETSAT | c.1774T>G p.L592V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV55525077; called by muse, mutect2, varscan2
- RUFY3 | c.1565A>C p.K522T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV66814405; called by muse, mutect2, varscan2
- SLC25A52 | c.605G>A p.G202D (on ENST00000672005; = p.G192D on NM_001034172.4) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV52501818; called by muse, mutect2
- SLC37A1 | c.74T>G p.F25C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100721562; called by muse, mutect2
- SPHK2 | c.1450T>C p.S484P | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV55335511; called by muse, mutect2
- SRBD1 | c.1595G>A p.S532N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV55396730; called by muse, mutect2, varscan2
- TBX4 | c.309A>C p.K103N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV53605696; called by muse, mutect2, varscan2
- TDP2 | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61966608; called by muse, mutect2, varscan2
- TIAM1 | c.4722T>G p.I1574M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV54541331; called by muse, mutect2, varscan2
- TOB1 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 14/238 reads (6%) | catalogued as COSV52149885; called by muse, mutect2
- TRIM29 | c.1279A>C p.M427L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV59279410; called by muse, mutect2, varscan2
- TTK | c.976A>C p.N326H | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57882310; called by muse, mutect2
- TTLL7 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as rs945289697, COSV53082122; called by muse, mutect2, varscan2
- TTN | c.28085T>G p.I9362S (on ENST00000591111; = p.I8435S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | PolyPhen benign (0.242); catalogued as COSV59931476; called by muse, mutect2, varscan2
- TUSC3 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV65878868; called by muse, mutect2, varscan2
- UBR5 | c.2016A>C p.K672N | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55282100; called by muse, mutect2, varscan2
- USP12 | c.123A>T p.L41F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV56655074; called by muse, mutect2, varscan2
- UTP14A | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.096); catalogued as COSV64086386; called by muse, mutect2, varscan2
- UTP20 | c.3263T>G p.V1088G | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs1204358919, COSV55373707; called by muse, mutect2
- VEGFC | c.1212A>C p.E404D | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54595023; called by muse, mutect2, varscan2
- WASHC2C | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1554881926, COSV60490454; called by muse, mutect2, varscan2
- WDR19 | c.452A>C p.N151T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV56462838; called by muse, mutect2, varscan2
- ZNF391 | c.156A>C p.E52D | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55122129, COSV99772598; called by muse, mutect2, varscan2
- ZNF74 | c.137A>C p.K46T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.238); catalogued as COSV62620325; called by muse, mutect2, varscan2
- ABCA1 | c.2129T>A p.L710Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CFAP65 | c.437_439dup p.E146dup (on ENST00000341552 / NM_194302.4; = p.E81dup on NM_152389.4) | In Frame Ins (INS) | VAF 36/113 reads (32%) | called by pindel, varscan2
- KLF16 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCUB | c.926T>G p.L309R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NT5DC3 | c.1118T>G p.F373C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RPLP2 | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TAOK2 | c.3494G>T p.S1165I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ASB6 | c.285C>T p.L95= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV52964580; called by muse, mutect2, varscan2
- EXOC1 | c.58C>T p.L20= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as COSV62119426; called by muse, mutect2, varscan2
- GALNS | c.990C>T p.V330= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV51936097; called by muse, mutect2, varscan2
- GFAP | c.916C>T p.L306= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV53649336; called by muse, mutect2, varscan2
- IGKV3D-20 | c.342C>T p.S114= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1260473628; called by mutect2, varscan2
- MEIOC | c.1401T>G p.S467= | Silent (SNP) | VAF 44/181 reads (24%) | called by muse, mutect2, varscan2
- MUC17 | c.3484T>C p.L1162= | Silent (SNP) | VAF 90/284 reads (32%) | catalogued as COSV60282467; called by muse, mutect2, varscan2
- OR6C2 | c.630T>G p.V210= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as COSV59515712, COSV59516905; called by muse, mutect2, varscan2
- PCDHA6 | c.2079G>A p.L693= | Silent (SNP) | VAF 44/80 reads (55%) | catalogued as COSV65342546; called by muse, mutect2, varscan2
- PRAMEF12 | c.351T>C p.S117= | Silent (SNP) | VAF 19/215 reads (9%) | catalogued as COSV63214698; called by muse, mutect2
- PSG2 | c.816T>C p.S272= | Silent (SNP) | VAF 52/114 reads (46%) | catalogued as COSV61544747; called by muse, varscan2
- RAP1GDS1 | c.807T>C p.C269= (on ENST00000408927 / NM_001100427.2; = p.C270= on NM_021159.5) | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs1231929014, COSV52785397; called by muse, mutect2, varscan2
- RELN | c.5319A>C p.S1773= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV58990440; called by muse, mutect2, varscan2
- SLC6A12 | c.1536T>C p.T512= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV62884191; called by muse, mutect2, varscan2
- SP1 | c.2357G>A p.*786= (on ENST00000327443 / NM_138473.3; = p.*779= on NM_003109.1) | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV59402068; called by muse, mutect2
- TMEM198 | c.348G>A p.V116= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs759095370, COSV54714611; called by muse, mutect2
- UBA6 | c.1515C>T p.N505= | Silent (SNP) | VAF 76/238 reads (32%) | catalogued as COSV59175139; called by muse, mutect2, varscan2
- ZXDA | c.1773C>A p.T591= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV62387616; called by muse, mutect2, varscan2
- MIR329-2 | n.64T>C | RNA (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- MIR517A | n.49A>G | RNA (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- SSPOP | n.6897T>G | RNA (SNP) | VAF 71/203 reads (35%) | catalogued as COSV50486756; called by muse, mutect2, varscan2
- ZNF271P | n.1374T>C | RNA (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
